Somatic mutation profile of tumor specimen MP2PRT-PARTXF-TBP1-A (aliquot MP2PRT-PARTXF-TBP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PARTXF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,090 days).
Specimen MP2PRT-PARTXF-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2deb639d-dc9d-4fb3-9f64-22927ce2c0ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARTXF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARTXF-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0e91475-21f1-4922-9f27-2c9fa4d67d26

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 14, Silent 9, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 84/244 reads (34%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- DNAH5 | c.6407C>T p.T2136M | Missense Mutation (SNP) | VAF 87/265 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as rs140690090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DRP2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 30/548 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.961); catalogued as rs748759701, COSV65811124; called by muse, mutect2
- FAM151A | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs574947604, COSV56366128; called by muse, mutect2
- HIF3A | c.1643G>A p.R548Q (on ENST00000377670 / NM_152795.4; = p.R479Q on NM_022462.4) | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs765904001, COSV52200182, COSV52206135; called by muse, mutect2
- IGSF21 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 27/371 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.401); catalogued as rs779760361, COSV52126192; called by muse, mutect2
- KCNC3 | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 131/357 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.02); catalogued as rs748015812, COSV100979370; called by muse, mutect2, varscan2
- MUC16 | c.34391T>G p.V11464G | Missense Mutation (SNP) | VAF 12/319 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.611); catalogued as rs1458450146; called by muse, mutect2
- NPNT | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 98/437 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201656446; called by muse, mutect2, varscan2
- NRXN1 | c.2233C>T p.R745W | Missense Mutation (SNP) | VAF 110/333 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750613816, COSV58436399, COSV58451818; called by muse, mutect2, varscan2
- PCDHA13 | c.1705G>A p.G569R | Missense Mutation (SNP) | VAF 30/456 reads (7%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as rs782157297; called by muse, mutect2
- IFT140 | c.2004_2019del p.E668Dfs*21 | Frame Shift Del (DEL) | VAF 68/270 reads (25%) | called by pindel, varscan2
- MIDN | c.1025C>A p.A342D | Missense Mutation (SNP) | VAF 179/454 reads (39%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- NRIP1 | c.2606_2607insCCCCCGAGTCC p.F870Pfs*8 | Frame Shift Ins (INS) | VAF 60/396 reads (15%) | called by pindel, varscan2
- NRIP1 | c.2601A>T p.E867D | Missense Mutation (SNP) | VAF 70/414 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.84); called by muse, varscan2
- PAPOLG | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 73/216 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ZNF165 | c.143G>T p.C48F | Missense Mutation (SNP) | VAF 93/358 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- ABLIM2 | c.1734G>A p.S578= (on ENST00000341937 / NM_001130084.2; = p.S488= on NM_032432.5) | Silent (SNP) | VAF 81/402 reads (20%) | catalogued as rs369627910; called by muse, mutect2, varscan2
- C10orf90 | c.456C>T p.R152= | Silent (SNP) | VAF 209/652 reads (32%) | catalogued as COSV52949277; called by muse, mutect2, varscan2
- CRIP1 | c.213C>T p.A71= | Silent (SNP) | VAF 126/465 reads (27%) | catalogued as rs201961496; called by muse, mutect2, varscan2
- HECW1 | c.708G>A p.G236= | Silent (SNP) | VAF 101/316 reads (32%) | catalogued as rs202123661; called by muse, mutect2, varscan2
- MERTK | c.2589C>T p.D863= | Silent (SNP) | VAF 111/307 reads (36%) | catalogued as rs759444240, COSV54928046; called by muse, mutect2, varscan2
- MUC5B | c.2994C>T p.H998= | Silent (SNP) | VAF 87/281 reads (31%) | catalogued as rs765653240; called by muse, mutect2, varscan2
- STAB1 | c.2877C>T p.H959= | Silent (SNP) | VAF 104/266 reads (39%) | catalogued as rs373105537; called by muse, mutect2, varscan2
- TENM3 | c.1668C>T p.N556= | Silent (SNP) | VAF 68/325 reads (21%) | catalogued as rs372557342, COSV69300737; called by muse, mutect2, varscan2
- USP6 | c.1449C>T p.S483= | Silent (SNP) | VAF 98/461 reads (21%) | called by muse, mutect2, varscan2
